Surgical pathology report (de-identified scan), TCGA case TCGA-MO-A47P, project TCGA-SARC (Sarcoma), tissue source site ILSBio, specimen TCGA-MO-A47P-01A (Primary Tumor).

[page 1 of 5]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-O-3
Liposarcoma, well differentiate 8851/3
Site CACF
Retroperitoneum C48.0
path
Kidney C64.9
JW 7/25/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	Caucasian	
☐ Male ☒ Female		☐ Divorced ☐ Widow		Blood Pressure

HISTORY OF PRESENT ILLNESS
Chief Complaints: Fever; abdominal pain;
Symptoms: Hematuria; Weight loss.
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 5]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY			
Menopausal Status	Date of First Menses	# of Pregnancies	
☒ Pre-menopausal	12 years old	02	
☐ Peri-Menopausal	Date of Last Menses	# of Live Births	
☐ Post-menopausal		02	
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____			☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 5]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	A tumor was found in the right kidney	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS	
Preoperative Clinical Diagnosis	
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis
Clinical Staging	Date of Diagnosis
T 1 N 0 M 0 Stage: I	

Treatment Information

SURGICAL TREATMENT		
Procedure	Date of Procedure	
Resection of the right kidney		
Primary Tumor		
Organ	Detailed Location	Size
Kidney tumor	right kidney	3.5 x 3.5 x 1 cm
Extension of Tumor		
Lymph Nodes		
Description	Location of Lymph Nodes	# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes		
Dissected Lymph Nodes		
Distant Metastasis		
Organ	Detailed Location	Size
Surgical Staging		
T 1 N 0 M 0 Stage: I		

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 5]
Pathology Form

Specimen Information

Collected by:

Date:

Time:

Preserved by:

Date:

Time:

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
7	0	4	0			4	0
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Kidney Tumor	3.5 x 3 x 1 cm		cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 1 N 0 M 0 Stage: 7			

Notes:

[page 5 of 5]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION		+	-	STRUCTURAL PATTERN		+	-
Diffuse		X		Streaming			
Mosaic			X	Storiform			
Necrosis			X	Fibrosis			
Lymphocytic Infiltration			X	Palisading			
Vascular Invasion			X	Cystic Degeneration			
Clusterized			X	Bleeding			
Alveolar Formation			X	Myxoid Change			
Indian File			X	Psammoma/Calcification			

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell			Glandular cell			Round Cell	X		Large Cell		
Spindle Cell			Cell Stratification			Fibroblast	X		Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast	X		Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		
Otherwise Specified: P1 D2 D3 D4 85%											

2. Cellular Differentiation:

Well	Moderately	Poor
D		

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism		X		
Nucleolar Prominent		X		
Multinucleated Giant Cell		X		
Mitotic Activity		X		
Nuclear Grade		2		

Histological Diagnosis: Well differentiated Liposarcoma -

Comments: _____

G-1

Director, Research Pathology

Date

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

PATHOLOGIST STAFF FOR RECEIVING USE ONLY

DQ - only de-differentiated cases are allowable. Case missed being B2 pre-reviews and went thru pipeline - justified - Case will be annotated.

B2

Criteria	7/18/13	Yes	No
Diagnosis Discrepancy	Well-diff	✓	✓

Source: NCI Genomic Data Commons file 22fa52b8-0194-48f7-9538-c31b0253aa69 (TCGA-MO-A47P.6E67AAA5-BC34-4409-B526-681204C85FB5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).